RC case RC-B65C — RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature T- and NK-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1b66a62a-d4be-4fdb-abb1-01061838a67d

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Country of residence at enrollment: United States; Year of birth: 1950; Vital status: Alive; Country of birth: United States.

Diagnoses (2)
1. T-cell large granular lymphocytic leukemia (the primary disease): ICD-O-3 morphology code: 9831/3; ICD-10 code: C84; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Blood; Classification of tumor: primary; Age at diagnosis: 68.0 years (24,853 days); Year of diagnosis: 2018; Method of diagnosis: Blood Draw; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: Yes; Prior treatment: No; Ann Arbor extranodal involvement: Yes; International Prognostic Index (IPI): High-Intermediate Risk; Sites of involvement: Bone marrow / Peripheral blood.
   Pathology details: Bone marrow malignant cells: Yes; Timepoint category: Initial Diagnosis.
   Recorded as not given: Organ Transplantation; Stem Cell Transplantation, NOS.
2. Clear cell carcinoma: ICD-O-3 morphology code: 8310/3; Tissue or organ of origin: Kidney, NOS; Laterality: Right; Classification of tumor: Synchronous primary; Age at diagnosis: 68.1 years (24,861 days); Year of diagnosis: 2018; Days to diagnosis: 8 days.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 74 days; Treatment anatomic sites: Kidney.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (2 entries)
- Day 0 (initial diagnosis): Karnofsky performance status: 80.
- Days to follow up: 211 days; Disease response: With Tumor.

Molecular and laboratory tests
- Lactate Dehydrogenase 982 U/L.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Anemia / Hypertension / Sleep Apnea / Aortic Valve Insufficiency / Depression.
- Timepoint category: Prior to Diagnosis; Immunosuppressive treatment type: Other.
- Timepoint category: Initial Diagnosis; Weight: 100 kg; Height: 175 cm; BMI: 32.7.
- Timepoint category: Prior to Diagnosis; Immunosuppressive treatment type: Prednisone.

Exposures
- Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 6.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample RC-B65C-NB1-A: Tissue type: Normal; Specimen type: Granulocytes; Preservation method: Frozen.
- Sample RC-B65C-TBP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
